CPTAC case C3N-03884 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cad8f812-c1cd-4ad8-97cf-4aef0cda8b69

Demographics
Sex at birth: female; Race: asian; Year of birth: 1953; Vital status: Dead; Days to death: 680 days (1.9 years); Year of death: 2020; Country of birth: China.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 64.6 years (23,590 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 680 days (1.9 years); Progression or recurrence: yes; Days to last follow up: 598 days (1.6 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.3 cm; Lymph node involvement: Positive; Lymph nodes positive: 4; Lymph nodes tested: 41; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 368 days (1.0 years); Disease response: Stable Disease; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 598 days (1.6 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 455 days (1.2 years); Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 49 kg; Height: 155 cm; BMI: 20.4.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03884-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2.
- Sample C3N-03884-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 132 mg; Time between clamping and freezing: 13 minutes; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03884-22: Section location: Head; Percent tumor nuclei: 20; Percent necrosis: 0.
- Sample C3N-03884-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 180 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03884-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -6 days; Method of sample procurement: Blood Draw.
